Somatic mutation profile of tumor specimen TARGET-30-PATRJG-01A (aliquot TARGET-30-PATRJG-01A-01D) from TARGET case TARGET-30-PATRJG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.0 years (1,104 days).
Specimen TARGET-30-PATRJG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d2475e0-5c0b-4487-a4c3-b09532432341.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATRJG-10A (Blood Derived Normal), aliquot TARGET-30-PATRJG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2429cfb5-a15d-4811-a426-49f9323a7a14

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3520T>C p.F1174L | Missense Mutation (SNP) | VAF 44/131 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs281864719, CM113795, COSV66556166, COSV66559314, COSV66568713; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNTN5 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54357246; called by muse, mutect2, varscan2
